Somatic mutation profile of tumor specimen ALCH-AFEG-TTP1-A (aliquot ALCH-AFEG-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AFEG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 83.6 years (30,540 days).
Specimen ALCH-AFEG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 451904aa-3d55-48f0-a7c1-9dbcfbabf25a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFEG-NB1-A (Blood Derived Normal), aliquot ALCH-AFEG-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db78e77a-a49e-40e1-9686-ba568beeac0e

The open-access MAF lists 301 somatic variants for this specimen: 209 protein-altering or splice-affecting, 51 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 51, Nonsense Mutation 20, Intron 19, 5'UTR 7, RNA 7, Splice Region 4, Splice Site 4, 3'Flank 3, 5'Flank 3, Frame Shift Del 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 29/282 reads (10%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.5104C>T p.R1702* | Nonsense Mutation (SNP) | VAF 30/302 reads (10%) | catalogued as rs886043414, COSV56407907; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 52/328 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.751A>T p.I251F | Missense Mutation (SNP) | VAF 39/379 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM114005, COSV52677403, COSV52702261, COSV52772679, COSV52927118; called by muse, mutect2
- ACAP3 | c.1812C>T p.R604= | Splice Region (SNP) | VAF 10/96 reads (10%) | catalogued as COSV57639490; called by muse, mutect2, varscan2
- ACE | c.2482A>G p.M828V | Missense Mutation (SNP) | VAF 57/516 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs890006891; called by muse, mutect2, varscan2
- ANKRD30A | c.2149T>A p.L717I (on ENST00000611781; = p.L661I on NM_052997.2) | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.745); catalogued as rs1219959990; called by muse, mutect2
- AP3M2 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1395502636, COSV51530575; called by muse, mutect2
- ASIC2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290030167, COSV63324569; called by muse, mutect2
- ATP7B | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 86/900 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs529307157, COSV54442102; called by muse, mutect2
- AZGP1 | c.338-1G>T p.X113_splice | Splice Site (SNP) | VAF 41/256 reads (16%) | catalogued as rs1420421128; called by muse, mutect2, varscan2
- BET1 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99747210; called by muse, varscan2
- CARMIL3 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV57725284; called by muse, mutect2
- CELSR1 | c.5513G>A p.R1838Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as rs368531321; called by mutect2, varscan2
- CFHR5 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs943920438, COSV56819294; called by muse, mutect2
- DPYSL5 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs755205638, COSV56512346, COSV99982937; called by muse, mutect2, varscan2
- DYNC2H1 | c.7657A>G p.T2553A | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1465828774; called by muse, mutect2, varscan2
- ENPP3 | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100717757; called by muse, mutect2
- EPHA3 | c.1564C>A p.R522S | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.097); catalogued as rs759973751, COSV60697932, COSV60700692; called by muse, mutect2
- EPHA6 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 14/225 reads (6%) | catalogued as rs1369792311; called by muse, mutect2
- EYS | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 48/627 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.431); catalogued as COSV100676891; called by muse, mutect2
- FASTKD1 | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as rs1237554669; called by muse, mutect2
- FAT1 | c.11782G>T p.D3928Y | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71675820; called by muse, mutect2
- GASK1B | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338948266; called by muse, mutect2
- GMPS | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs772483854; called by muse, mutect2
- GPA33 | c.107del p.G36Efs*72 | Frame Shift Del (DEL) | VAF 21/186 reads (11%) | catalogued as COSV100900986; called by mutect2, pindel, varscan2
- GPT2 | c.203T>C p.I68T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1409759871; called by muse, mutect2, varscan2
- HEPH | c.1188G>A p.M396I (on ENST00000343002; = p.M129I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100295201, COSV57958565; called by muse, mutect2, varscan2
- IMMT | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs1278755798, COSV54479362; called by muse, mutect2
- ITGAD | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1434869205; called by muse, mutect2, varscan2
- KMT2A | c.5554G>A p.D1852N | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV63283626; called by muse, mutect2
- LRP1B | c.2801G>T p.C934F | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV67204507; called by muse, mutect2
- LRRIQ1 | c.3739G>A p.G1247R | Missense Mutation (SNP) | VAF 46/662 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV67838440; called by muse, mutect2
- MAGEA12 | c.512G>C p.R171P | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1556833500, COSV100757013, COSV63295146; called by mutect2, varscan2
- MAGI3 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772074544, COSV56830067; called by muse, mutect2
- NAV3 | c.5972G>T p.R1991I (on ENST00000397909 / NM_001024383.2; = p.R1969I on NM_014903.6) | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57076806; called by muse, mutect2
- NLRP12 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV60751156; called by muse, mutect2
- OR2A14 | c.225C>A p.N75K | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV68717887; called by muse, mutect2, varscan2
- OR2M7 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV58739273; called by muse, mutect2
- OR5AP2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 14/355 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100266315; called by muse, mutect2
- PABPC4 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV63293637; called by muse, mutect2
- PCDHGB5 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 29/264 reads (11%) | catalogued as COSV54000132; called by muse, mutect2, varscan2
- PKHD1L1 | c.4207C>A p.H1403N | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV65755179; called by muse, mutect2
- PLCE1 | c.1945G>T p.A649S | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779280589; called by muse, mutect2
- POTEE | c.2320G>A p.G774S | Missense Mutation (SNP) | VAF 40/834 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.944); catalogued as rs571289203, COSV100387337; called by muse, mutect2
- RASA1 | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV57191377, COSV57201384; called by muse, mutect2
- ROS1 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV63856460; called by muse, mutect2
- RPAP1 | c.2627C>A p.S876* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV58543002; called by muse, mutect2, varscan2
- RYR2 | c.9442G>C p.V3148L | Missense Mutation (SNP) | VAF 27/354 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); catalogued as COSV100771577, COSV63677375; called by muse, mutect2
- SCN7A | c.1417T>A p.L473I | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV101313378; called by muse, mutect2
- SERGEF | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1011499232; called by muse, mutect2, varscan2
- SLC16A3 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760433852; called by muse, mutect2
- SLC49A3 | c.922C>T p.R308W (on ENST00000404286 / NM_001294341.2; = p.R307W on NM_032219.4) | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs200269023; called by muse, mutect2
- SOS1 | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV101216581; called by muse, mutect2
- TCN2 | c.1268G>T p.R423M | Missense Mutation (SNP) | VAF 42/525 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53193316; called by muse, mutect2
- TDRD6 | c.508G>T p.V170F | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377517102, COSV60174750; called by muse, mutect2, varscan2
- UGT2B28 | c.677T>C p.M226T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs746719102; called by mutect2, varscan2
- UNC79 | c.2018G>T p.R673L (on ENST00000393151 / NM_001346218.2; = p.R496L on NM_020818.5) | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56392950; called by muse, mutect2
- WDHD1 | c.3184A>G p.R1062G | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1258040644; called by muse, mutect2
- ZNF385B | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 38/576 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69800806; called by muse, mutect2
- ZNF536 | c.2254G>T p.D752Y | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62831838; called by muse, mutect2
- ZNF792 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.615); catalogued as COSV68693040; called by muse, mutect2, varscan2
- AADACL3 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ABCA12 | c.6817G>A p.V2273I (on ENST00000272895 / NM_173076.3; = p.V1955I on NM_015657.3) | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACBD7 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.189); called by muse, mutect2
- ACSM4 | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADAM23 | c.1633T>C p.C545R | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRA3 | c.2823G>C p.Q941H | Missense Mutation (SNP) | VAF 30/485 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.942); called by muse, mutect2
- ADGRB3 | c.3023G>C p.G1008A | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRG4 | c.3370G>C p.A1124P | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- AHCY | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 38/435 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2
- AHCY | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- AMBRA1 | c.1448G>A p.G483E (on ENST00000458649 / NM_001367468.1; = p.G393E on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/644 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2
- AP1B1 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 13/195 reads (7%) | called by muse, mutect2
- AQR | c.2390+1G>T p.X797_splice | Splice Site (SNP) | VAF 14/367 reads (4%) | called by muse, mutect2
- ARID2 | c.4543G>T p.V1515L | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2
- ARMC4 | c.2726C>A p.A909E | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- ASB3 | c.964A>G p.M322V | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.184); called by muse, mutect2
- ATP11A | c.2038G>T p.G680W | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ATP2B2 | c.917G>A p.G306D (on ENST00000352432; = p.G317D on NM_001001331.4) | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2
- ATP2C1 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 17/514 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- BEND6 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 18/442 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); called by muse, mutect2
- BRCA1 | c.5308G>T p.G1770W | Missense Mutation (SNP) | VAF 38/534 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- BRINP3 | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 37/478 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- BTNL3 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BTNL3 | c.578T>A p.I193N | Missense Mutation (SNP) | VAF 46/518 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- C3 | c.2353G>T p.G785* | Nonsense Mutation (SNP) | VAF 42/460 reads (9%) | called by muse, mutect2
- C4orf51 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.038); called by muse, mutect2
- CAMKMT | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CASP8AP2 | c.3928A>T p.M1310L | Missense Mutation (SNP) | VAF 28/407 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CCDC50 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 65/473 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CFAP70 | c.2854C>T p.L952F | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CNGB3 | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 50/494 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- COL25A1 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD1 | c.5917G>T p.A1973S (on ENST00000520002; = p.A1972S on NM_033225.6) | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CTDP1 | c.2489G>C p.G830A | Missense Mutation (SNP) | VAF 29/524 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK4 | c.1066+7G>T | Splice Region (SNP) | VAF 35/608 reads (6%) | called by muse, mutect2
- DVL3 | c.979G>C p.G327R | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- DYNC1H1 | c.11828C>G p.A3943G | Missense Mutation (SNP) | VAF 39/523 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.141); called by muse, mutect2
- EEPD1 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2
- FCRL4 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.123); called by muse, mutect2
- FMN1 | c.1613T>A p.L538H | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- FRG2C | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 28/1011 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); called by muse, mutect2
- FSCB | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2, varscan2
- GALNT12 | c.1395T>G p.D465E | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.096); called by muse, mutect2
- GALNT9 | c.1165A>G p.I389V (on ENST00000328957 / NM_001122636.2; = p.I23V on NM_021808.3) | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.036); called by muse, mutect2
- GBE1 | c.1779A>T p.R593S | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.101); called by muse, mutect2
- GJB1 | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- GLI2 | c.438G>T p.R146S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- GPC2 | c.236G>T p.R79M | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); called by muse, mutect2
- GPR65 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2
- GRIK2 | c.2189C>G p.T730S | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- GRIN2B | c.1543A>T p.I515F | Missense Mutation (SNP) | VAF 43/423 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- GUCY1A1 | c.1891G>A p.G631S | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- HCN2 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- HDAC9 | c.2452G>T p.D818Y | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD1 | c.2378A>G p.N793S | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HECW1 | c.452T>C p.F151S | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HELB | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- HHLA1 | c.1397T>A p.L466Q | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HHLA1 | c.29C>A p.S10* | Nonsense Mutation (SNP) | VAF 43/384 reads (11%) | called by muse, mutect2, varscan2
- HLTF | c.1988T>C p.V663A | Missense Mutation (SNP) | VAF 46/566 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HPR | c.862T>A p.Y288N | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.942); called by muse, mutect2
- JPH2 | c.2030T>A p.I677N | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KDM5D | c.3082-2A>G p.X1028_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- KIAA1549L | c.2759A>T p.H920L (on ENST00000321505; = p.H1217L on NM_012194.3) | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- KIAA1671 | c.5104G>T p.D1702Y | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA2 | c.6286G>A p.D2096N | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.328); called by muse, mutect2
- LIFR | c.1340C>A p.T447K | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LRRC27 | c.1004dup p.E336Gfs*69 | Frame Shift Ins (INS) | VAF 22/226 reads (10%) | called by mutect2, pindel
- LRRC37A3 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 46/764 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2
- MARF1 | c.5122G>T p.E1708* | Nonsense Mutation (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2
- MDGA2 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MED13L | c.4046A>T p.N1349I | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2
- MIEF1 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 26/379 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- MMS22L | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by muse, mutect2
- MORC1 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MOS | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2
- MOV10 | c.2509-8C>T | Splice Region (SNP) | VAF 27/251 reads (11%) | called by muse, mutect2, varscan2
- MYH10 | c.3747G>T p.E1249D | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.028); called by muse, mutect2
- MYO16 | c.1285C>A p.Q429K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); called by mutect2, varscan2
- MYO18B | c.7091A>T p.K2364I | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2
- NCAM2 | c.1616C>A p.S539* | Nonsense Mutation (SNP) | VAF 11/183 reads (6%) | called by muse, mutect2
- NCOA5 | c.533A>C p.E178A | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2
- NELL1 | c.1589T>A p.V530E | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- NME8 | c.622-1G>T p.X208_splice | Splice Site (SNP) | VAF 33/478 reads (7%) | called by muse, mutect2
- NOD2 | c.1473G>T p.M491I | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR1G1 | c.619G>T p.G207* | Nonsense Mutation (SNP) | VAF 39/350 reads (11%) | called by muse, mutect2, varscan2
- OR2B6 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- OR2L2 | c.434C>A p.T145K | Missense Mutation (SNP) | VAF 37/477 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.694); called by muse, mutect2
- OR51E2 | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 32/417 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- OR52L1 | c.301G>C p.A101P | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2
- OR6Y1 | c.616T>A p.F206I | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2
- OXCT1 | c.559A>T p.R187* | Nonsense Mutation (SNP) | VAF 48/580 reads (8%) | called by muse, mutect2
- PEX5L | c.110C>A p.A37E | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PGM2L1 | c.1112A>G p.K371R | Missense Mutation (SNP) | VAF 50/589 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.014); called by muse, mutect2
- PITRM1 | c.1133T>A p.V378D | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- PODXL2 | c.1685C>A p.S562* | Nonsense Mutation (SNP) | VAF 16/304 reads (5%) | called by muse, mutect2
- PPM1D | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.06); called by muse, mutect2
- PRDM14 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.035); called by muse, mutect2
- PTPN12 | c.1352A>T p.D451V | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- RAB6D | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 38/500 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- RALA | c.405A>T p.R135S | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2
- RELL1 | c.599G>T p.W200L | Missense Mutation (SNP) | VAF 48/733 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2
- RELN | c.7130T>A p.F2377Y | Missense Mutation (SNP) | VAF 78/497 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RFX7 | c.2911G>C p.G971R (on ENST00000559447 / NM_001368074.1; = p.G1068R on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.946); called by muse, mutect2
- RNGTT | c.1175G>C p.R392P | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RP1L1 | c.4673C>A p.A1558D | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- RPS6KL1 | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); called by muse, mutect2
- SAMD14 | c.1208A>C p.Q403P (on ENST00000330175 / NM_001257359.2; = p.Q431P on NM_174920.4) | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SCMH1 | c.1291G>A p.E431K (on ENST00000326197 / NM_001031694.2; = p.E384K on NM_012236.4) | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.114); called by muse, mutect2
- SCNN1G | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 28/353 reads (8%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.829); called by muse, mutect2
- SCRN1 | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2
- SEC16A | c.4250G>T p.G1417V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2
- SHH | c.1357C>A p.H453N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLC39A8 | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 26/290 reads (9%) | called by muse, mutect2
- SLC4A8 | c.2717T>A p.V906E | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMCHD1 | c.4642G>A p.D1548N | Missense Mutation (SNP) | VAF 23/300 reads (8%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.852); called by muse, mutect2
- SMG1 | c.3239T>A p.L1080* | Nonsense Mutation (SNP) | VAF 22/458 reads (5%) | called by muse, mutect2
- SOS1 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.701); called by muse, mutect2
- SOX2 | c.346A>T p.T116S | Missense Mutation (SNP) | VAF 51/710 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.348); called by muse, mutect2
- SYN3 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2
- TANC1 | c.956C>G p.S319* | Nonsense Mutation (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- TFAP2D | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 42/580 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- THSD7A | c.3986T>C p.M1329T | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.102); called by muse, mutect2
- THSD7A | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 33/650 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2
- TLR8 | c.2598G>C p.K866N (on ENST00000218032 / NM_138636.5; = p.K884N on NM_016610.4) | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM163 | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- TNFSF9 | c.452G>C p.R151P | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TNKS2 | c.1987A>T p.K663* | Nonsense Mutation (SNP) | VAF 37/413 reads (9%) | called by muse, mutect2
- TPR | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.115); called by muse, mutect2
- TRDN | c.76A>C p.K26Q | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.231); called by muse, mutect2
- TRPM2 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2
- UBE2J1 | c.233T>G p.L78R | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- UEVLD | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- UFM1 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- UNCX | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- VCPIP1 | c.2186A>T p.K729I | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- VSIG4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- VWA8 | c.2540A>T p.D847V | Missense Mutation (SNP) | VAF 31/357 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- WRN | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 38/500 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZEB2 | c.332-5C>A | Splice Region (SNP) | VAF 22/405 reads (5%) | called by muse, mutect2
- ZFHX4 | c.3226G>T p.G1076C | Missense Mutation (SNP) | VAF 31/466 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF296 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 32/432 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2
- ZNF461 | c.1087G>T p.G363* | Nonsense Mutation (SNP) | VAF 23/232 reads (10%) | called by muse, mutect2, varscan2
- ZNF536 | c.2253G>T p.K751N | Missense Mutation (SNP) | VAF 9/223 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF699 | c.1555A>T p.T519S | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2
- ZNF711 | c.1207_1211del p.K403Sfs*3 | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | called by mutect2, pindel, varscan2
- ZNF850 | c.2598G>C p.E866D | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2
- BMPR1A | c.342A>G p.P114= | Silent (SNP) | VAF 27/480 reads (6%) | called by muse, mutect2
- BOD1L1 | c.8079G>T p.L2693= | Silent (SNP) | VAF 36/363 reads (10%) | called by muse, mutect2
- BRCA1 | c.5310G>T p.G1770= | Silent (SNP) | VAF 38/527 reads (7%) | catalogued as CD032455; called by muse, mutect2
- C2CD5 | c.1914A>G p.E638= | Silent (SNP) | VAF 25/237 reads (11%) | called by muse, mutect2
- CACTIN | c.1698G>T p.A566= | Silent (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2
- CCDC168 | c.16044C>A p.S5348= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as COSV59424097; called by muse, mutect2
- CCDC168 | c.13209T>A p.T4403= | Silent (SNP) | VAF 20/328 reads (6%) | catalogued as COSV59426426; called by muse, mutect2
- CDH23 | c.1473C>T p.T491= | Silent (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
- CEP170B | c.360G>A p.Q120= (on ENST00000453495; = p.Q50= on NM_015005.3) | Silent (SNP) | VAF 30/209 reads (14%) | called by muse, mutect2, varscan2
- CFAP57 | c.1185A>T p.L395= | Silent (SNP) | VAF 56/692 reads (8%) | called by muse, mutect2
- CFAP92 | c.1875C>T p.Y625= | Silent (SNP) | VAF 25/259 reads (10%) | called by muse, mutect2
- CRHR1 | c.196C>A p.R66= | Silent (SNP) | VAF 20/348 reads (6%) | called by muse, mutect2
- CSMD3 | c.1335T>G p.T445= | Silent (SNP) | VAF 21/267 reads (8%) | called by muse, mutect2
- DGKK | c.3489G>A p.L1163= | Silent (SNP) | VAF 32/248 reads (13%) | called by muse, mutect2, varscan2
- DNHD1 | c.3594A>T p.V1198= | Silent (SNP) | VAF 35/263 reads (13%) | called by muse, mutect2, varscan2
- EPX | c.552C>G p.G184= | Silent (SNP) | VAF 24/359 reads (7%) | called by muse, mutect2
- FAM163A | c.54C>T p.L18= | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as rs1323056441; called by muse, mutect2
- FAT3 | c.4563C>G p.A1521= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as rs762635092, COSV53102445, COSV53152681; called by muse, mutect2
- FBN3 | c.2514C>T p.L838= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs564001593; called by muse, mutect2, varscan2
- GRB10 | c.1359C>T p.S453= (on ENST00000398812; = p.S407= on NM_001001549.3) | Silent (SNP) | VAF 28/328 reads (9%) | catalogued as rs1001553225, COSV60011524; called by muse, mutect2
- HCN4 | c.3611G>A p.*1204= | Silent (SNP) | VAF 36/524 reads (7%) | called by muse, mutect2
- IGF1R | c.3996G>A p.G1332= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV51322771; called by muse, mutect2, varscan2
- KIAA1549L | c.3072C>A p.L1024= (on ENST00000321505; = p.L1321= on NM_012194.3) | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- MACF1 | c.20751C>T p.I6917= (on ENST00000372915; = p.I4962= on NM_012090.5) | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs369524203; called by muse, mutect2, varscan2
- MYH8 | c.5782C>A p.R1928= | Silent (SNP) | VAF 34/430 reads (8%) | called by muse, mutect2
- NAV3 | c.1794C>A p.T598= | Silent (SNP) | VAF 16/221 reads (7%) | catalogued as COSV99892299; called by muse, mutect2
- NPY1R | c.705T>C p.Y235= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, varscan2
- OR5B21 | c.270C>A p.I90= | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
- PAXIP1 | c.1749A>T p.P583= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- PCDH1 | c.432G>T p.V144= | Silent (SNP) | VAF 29/268 reads (11%) | called by muse, mutect2, varscan2
- PCDHB11 | c.780G>A p.L260= | Silent (SNP) | VAF 40/524 reads (8%) | catalogued as rs1554285320; called by muse, mutect2
- PCDHGA3 | c.1596G>T p.V532= | Silent (SNP) | VAF 38/420 reads (9%) | called by muse, mutect2
- PCDHGA8 | c.492G>T p.V164= | Silent (SNP) | VAF 28/270 reads (10%) | called by muse, mutect2
- PCSK4 | c.882C>T p.F294= | Silent (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- PKHD1 | c.10386C>A p.I3462= | Silent (SNP) | VAF 24/222 reads (11%) | called by muse, varscan2
- RGP1 | c.435C>T p.V145= | Silent (SNP) | VAF 13/264 reads (5%) | called by muse, mutect2
- RP1L1 | c.5145G>T p.T1715= | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- SLC22A11 | c.858G>A p.K286= | Silent (SNP) | VAF 12/297 reads (4%) | called by muse, mutect2
- SLC26A7 | c.585C>G p.V195= | Silent (SNP) | VAF 14/197 reads (7%) | called by muse, mutect2
- SORBS1 | c.1788T>C p.P596= | Silent (SNP) | VAF 12/191 reads (6%) | catalogued as rs1262163764; called by muse, mutect2
- STYXL2 | c.1225C>A p.R409= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54810905; called by muse, varscan2
- TENM3 | c.7398G>A p.S2466= | Silent (SNP) | VAF 25/297 reads (8%) | catalogued as rs1485977049; called by muse, mutect2
- TNR | c.3345C>A p.T1115= | Silent (SNP) | VAF 21/250 reads (8%) | called by muse, mutect2
- TRA2A | c.651G>T p.G217= | Silent (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- UTP20 | c.453G>A p.S151= | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as rs1290527449, COSV55376508; called by muse, mutect2
- WNT9A | c.834T>C p.G278= | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- ZC3H7B | c.549C>T p.L183= | Silent (SNP) | VAF 32/337 reads (9%) | catalogued as rs1569236725; called by muse, mutect2
- ZFPM1 | c.2913C>T p.G971= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, varscan2
- ZNF541 | c.1962C>T p.A654= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as rs1304262349; called by muse, mutect2, varscan2
- ZNF730 | c.33A>T p.I11= | Silent (SNP) | VAF 36/358 reads (10%) | called by muse, mutect2
- ZNF99 | c.1719T>A p.A573= | Silent (SNP) | VAF 22/382 reads (6%) | called by muse, mutect2
- AC072022.1 | n.314G>T | RNA (SNP) | VAF 47/245 reads (19%) | called by muse, mutect2, varscan2
- AGMO | c.1263+7094C>A | Intron (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- ARMT1 | c.-29G>T | 5'UTR (SNP) | VAF 16/204 reads (8%) | catalogued as rs1240855983; called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+38731G>C | Intron (SNP) | VAF 20/255 reads (8%) | called by muse, mutect2
- C22orf34 | n.202G>T | RNA (SNP) | VAF 28/214 reads (13%) | called by muse, mutect2
- CHIT1 | c.*419C>T | 3'UTR (SNP) | VAF 22/263 reads (8%) | called by muse, mutect2
- CLVS1 | c.-152+4191A>T | Intron (SNP) | VAF 15/224 reads (7%) | called by muse, mutect2
- COG5 | c.-69C>A | 5'UTR (SNP) | VAF 23/192 reads (12%) | called by muse, mutect2, varscan2
- CTAGE11P | n.407G>T | RNA (SNP) | VAF 48/687 reads (7%) | called by muse, mutect2
- CUL7 | c.2398-117G>T | Intron (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- DDX11 | c.792+30G>T | Intron (SNP) | VAF 18/170 reads (11%) | catalogued as rs780610580; called by muse, varscan2
- DMPK | c.161-110G>T | Intron (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- ENPP2 | c.-31C>T | 5'UTR (SNP) | VAF 19/244 reads (8%) | catalogued as COSV50019107; called by muse, mutect2
- FAM90A27P | n.1166C>A | RNA (SNP) | VAF 17/221 reads (8%) | called by muse, mutect2
- H3-3B | chr17:75784631 C>A | 5'Flank (SNP) | VAF 41/355 reads (12%) | called by muse, mutect2, varscan2
- HLA-B | c.619+47G>T | Intron (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- IPO8 | c.640-309G>T | Intron (SNP) | VAF 31/361 reads (9%) | called by muse, mutect2
- KCNIP4 | c.61+185561G>T | Intron (SNP) | VAF 17/320 reads (5%) | called by muse, mutect2
- LAIR2 | c.-37C>A | 5'UTR (SNP) | VAF 17/224 reads (8%) | called by muse, mutect2
- LIM2 | c.175+126G>C | Intron (SNP) | VAF 24/574 reads (4%) | called by muse, mutect2
- LRRC74A | c.217+48C>T | Intron (SNP) | VAF 30/386 reads (8%) | called by muse, mutect2
- MAPKAPK2 | c.1059+112A>T | Intron (SNP) | VAF 38/356 reads (11%) | called by muse, mutect2, varscan2
- NANOGNB | c.-54C>G | 5'UTR (SNP) | VAF 18/248 reads (7%) | catalogued as rs1267447451; called by muse, mutect2
- NLRP7 | c.2810+2768G>T | Intron (SNP) | VAF 20/376 reads (5%) | catalogued as COSV100051717; called by muse, mutect2
- NOC2LP2 | n.1705C>G | RNA (SNP) | VAF 35/452 reads (8%) | called by muse, mutect2
- PRB4 | c.-4C>T | 5'UTR (SNP) | VAF 30/390 reads (8%) | catalogued as rs775576905; called by muse, mutect2
- RN7SL484P | chr15:99791004 A>G | 5'Flank (SNP) | VAF 17/171 reads (10%) | called by muse, mutect2, varscan2
- S100A7 | c.-1G>C | 5'UTR (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100906666, COSV100906741; called by muse, mutect2
- SGCD | c.-1+2320T>A | Intron (SNP) | VAF 21/184 reads (11%) | called by muse, mutect2
- SLCO2A1 | chr3:133928495 G>T | 3'Flank (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- SNORD115-3 | n.28C>A | RNA (SNP) | VAF 13/338 reads (4%) | called by muse, mutect2
- SNORD116-22 | n.71C>A | RNA (SNP) | VAF 13/369 reads (4%) | called by muse, mutect2
- SRCIN1 | c.3372+768C>T | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as rs1047482492; called by muse, mutect2
- TAOK2 | chr16:29989636 A>G | 3'Flank (SNP) | VAF 48/415 reads (12%) | called by muse, mutect2, varscan2
- TMEM232 | n.1012-9376C>A | Intron (SNP) | VAF 25/330 reads (8%) | called by muse, mutect2
- TOMM34 | c.381-693G>A | Intron (SNP) | VAF 23/250 reads (9%) | catalogued as rs1402138666; called by muse, mutect2
- TOX2 | c.439-12132G>A | Intron (SNP) | VAF 28/370 reads (8%) | catalogued as rs1050611548; called by muse, mutect2
- TSHR | c.170+13G>T | Intron (SNP) | VAF 50/574 reads (9%) | called by muse, mutect2
- Y_RNA | chr7:23491108 A>T | 3'Flank (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- ZNF461 | c.*782C>A | 3'UTR (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- ZSWIM8 | chr10:73785638 C>A | 5'Flank (SNP) | VAF 17/264 reads (6%) | catalogued as rs1307935116; called by muse, mutect2
